CCDI case PBCIJC — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Thyroid gland.
https://portal.gdc.cancer.gov/cases/a612db57-dea3-43fd-9738-508f1527ecb8

Demographics
Sex at birth: male; Race: asian.

Diagnoses (1)
1. Papillary carcinoma, NOS: ICD-O-3 morphology code: 8050/3; Tissue or organ of origin: Thyroid gland; Age at diagnosis: 17.3 years (6,318 days).

Biospecimens (3 samples)
- Samples 0DU9MD, 0DU9N1 (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DU9N7: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
